CPTAC case C3L-00614 — Hematopoietic and reticuloendothelial systems — Myeloid Leukemias (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/10b96620-545a-4d3f-bad4-b97a9d0835a2

Demographics
Sex at birth: male; Race: white; Year of birth: 1956; Vital status: Dead; Days to death: 3 days; Year of death: 2017.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Hematopoietic system, NOS; Age at diagnosis: 60.6 years (22,119 days); Year of diagnosis: 2017; Days to last known disease status: 3 days; Days to last follow up: 3 days; Calgb risk group: Poor.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 3.

Other clinical attributes
- Weight: 126.55 kg; Height: 175.26 cm; BMI: 41.2; Comorbidities: Arthritis.

Biospecimens (5 samples)
- Samples C3L-00614-51, C3L-00614-52, C3L-00614-53 (3 with the same recorded description): Sample type: Buccal Cell Normal; Tissue type: Normal; Specimen type: Buccal Cells; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC).
- Samples C3L-00614-55, C3L-00614-59 (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Days to sample procurement: 1 day; Time between excision and freezing: 375 minutes; Method of sample procurement: Blood Draw; Diagnosis pathologically confirmed: Yes.
